FM case AD13794 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Esophagus.
https://portal.gdc.cancer.gov/cases/19039b60-4c59-4eb0-bed8-11872d10c0df

Male, 56.3 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the esophagus; metastasis biopsied or resected from the cardia. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
